Somatic mutation profile of tumor specimen HCM-BROD-0595-C43-06A (aliquot HCM-BROD-0595-C43-06A-11D-A80U-36) from HCMI case HCM-BROD-0595-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage 0; Age at diagnosis: 47.2 years (17,247 days).
Specimen HCM-BROD-0595-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfd436c8-73d1-4ddb-8cf9-f0ef544638a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0595-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0595-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1029107d-958f-444b-b5c2-2a2409d8e509

The open-access MAF lists 132 somatic variants for this specimen: 95 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 34, Splice Region 6, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, 3'UTR 1, Splice Site 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACOT11 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs139052769; called by muse, mutect2, varscan2
- ADAMTS18 | c.3337C>T p.R1113W | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs148910905; called by muse, mutect2, varscan2
- AGXT | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 199/211 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56753854; called by muse, mutect2, varscan2
- ANKK1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58274862; called by muse, mutect2, varscan2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 217/234 reads (93%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- CD163 | c.1736-8C>T | Splice Region (SNP) | VAF 134/383 reads (35%) | catalogued as COSV63129888; called by muse, mutect2, varscan2
- CNNM1 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1044720732; called by muse, mutect2, varscan2
- COL28A1 | c.927+1G>A p.X309_splice | Splice Site (SNP) | VAF 122/250 reads (49%) | catalogued as rs370508064; called by muse, mutect2, varscan2
- CRB1 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 298/647 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV66328793; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 160/187 reads (86%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DNAH17 | c.10135G>A p.E3379K | Missense Mutation (SNP) | VAF 226/230 reads (98%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); catalogued as rs865785284; called by muse, mutect2, varscan2
- EPHA3 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs200415022, COSV60720631; called by muse, mutect2, varscan2
- GRIA1 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53598315; called by muse, mutect2, varscan2
- GRIN2B | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 98/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761084398; called by muse, mutect2, varscan2
- IGSF5 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 190/456 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs780927418; called by muse, mutect2, varscan2
- IL36A | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 126/135 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52083544; called by muse, mutect2, varscan2
- IQCH | c.2587C>G p.L863V | Missense Mutation (SNP) | VAF 104/411 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as COSV60058629; called by muse, mutect2, varscan2
- KIF1B | c.3262T>G p.L1088V (on ENST00000377086 / NM_001365952.1; = p.L1042V on NM_015074.3) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as rs1001609597, COSV55818712; called by muse, mutect2, varscan2
- KIR2DL4 | c.527G>A p.R176H (on ENST00000396284; = p.R137H on NM_001080770.2) | Missense Mutation (SNP) | VAF 309/653 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs537400112, COSV60877656; called by muse, mutect2, varscan2
- KLF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 215/356 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53436163; called by muse, mutect2, varscan2
- LRRC3B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101185673; called by muse, mutect2, varscan2
- LYPD4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as rs1555831271; called by muse, mutect2, varscan2
- MAGED1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 183/205 reads (89%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs782402643, COSV58516219; called by muse, mutect2, varscan2
- NFIA | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 289/299 reads (97%) | SIFT tolerated, low confidence (0.91); catalogued as rs1218189561; called by muse, mutect2, varscan2
- OPA1 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 106/112 reads (95%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs766257852; called by muse, mutect2, varscan2
- OR52A1 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 226/246 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61093497; called by muse, mutect2, varscan2
- ORC5 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs267601218, COSV99857320; called by muse, mutect2, varscan2
- PKHD1 | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 304/501 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV61860281; called by muse, mutect2, varscan2
- PPARGC1A | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 112/343 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs762893416, COSV53525023; called by muse, mutect2, varscan2
- PWWP3B | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 137/722 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61798632; called by muse, mutect2, varscan2
- SNCAIP | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 126/239 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs143440334; called by muse, mutect2, varscan2
- SNTG1 | c.888C>A p.D296E | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs779227339; called by muse, mutect2, varscan2
- SPNS3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 188/191 reads (98%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs139407503; called by muse, mutect2, varscan2
- ST6GAL2 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 20/225 reads (9%) | PolyPhen probably damaging (1); catalogued as rs763640071; called by muse, mutect2
- SVEP1 | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57029299; called by muse, mutect2, varscan2
- SYT16 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 241/257 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs1409503101, COSV70859455; called by muse, mutect2, varscan2
- TONSL | c.2806C>T p.R936* | Nonsense Mutation (SNP) | VAF 89/375 reads (24%) | catalogued as rs1156410886, COSV68048801; called by muse, mutect2, varscan2
- TRPM6 | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 222/408 reads (54%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1440851175, COSV62507013, COSV62510751; called by muse, mutect2, varscan2
- VPS16 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 118/406 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558893855, COSV66792589; called by muse, mutect2, varscan2
- VSTM4 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs187843947; called by muse, mutect2, varscan2
- ZFHX4 | c.9616G>A p.E3206K | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV99268039; called by muse, varscan2
- ZNF831 | c.3322G>T p.G1108W | Missense Mutation (SNP) | VAF 272/614 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV64038804; called by muse, mutect2, varscan2
- ZNF99 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 150/261 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs970147679, COSV68054917; called by muse, mutect2, varscan2
- ADAMTS20 | c.5274_5300del p.Q1759_V1767del | In Frame Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- AEBP2 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ALS2 | c.4766C>T p.S1589L | Missense Mutation (SNP) | VAF 243/245 reads (99%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD2B | c.3523G>A p.D1175N | Missense Mutation (SNP) | VAF 199/211 reads (94%) | SIFT tolerated (0.18); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ATP7A | c.3244A>T p.S1082C | Missense Mutation (SNP) | VAF 62/497 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- C4orf50 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1B | c.6431C>T p.S2144F | Missense Mutation (SNP) | VAF 291/699 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CASS4 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 184/373 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CCNF | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 253/527 reads (48%) | called by muse, mutect2, varscan2
- CEP170 | c.2852A>G p.K951R | Missense Mutation (SNP) | VAF 143/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL14A1 | c.4605G>A p.Q1535= | Splice Region (SNP) | VAF 75/328 reads (23%) | called by muse, mutect2, varscan2
- COL26A1 | c.287G>A p.R96K (on ENST00000313669 / NM_001278563.3; = p.X94_splice on NM_133457.4) | Missense Mutation (SNP) | VAF 134/299 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- DYNLRB2 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 162/287 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EPHA10 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 341/361 reads (94%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABBR1 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 314/1015 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNT1 | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 116/189 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6A | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 88/710 reads (12%) | called by muse, varscan2
- GOLGB1 | c.6130G>C p.A2044P | Missense Mutation (SNP) | VAF 116/128 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2BC1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HK3 | c.1740C>T p.L580= | Splice Region (SNP) | VAF 130/259 reads (50%) | called by muse, mutect2, varscan2
- HOXC5 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 401/421 reads (95%) | SIFT tolerated (0.57); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- INPPL1 | c.958_967del p.L320* | Frame Shift Del (DEL) | VAF 206/226 reads (91%) | called by mutect2, pindel, varscan2
- MDFIC | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 119/230 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MEAF6 | c.91-8T>C | Splice Region (SNP) | VAF 137/397 reads (35%) | called by muse, mutect2, varscan2
- MXRA5 | c.6920G>A p.G2307E | Missense Mutation (SNP) | VAF 190/215 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH6 | c.4959G>A p.K1653= | Splice Region (SNP) | VAF 241/255 reads (95%) | called by muse, mutect2, varscan2
- MZF1 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 173/724 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, varscan2
- NEDD4L | c.1824A>T p.L608F (on ENST00000400345 / NM_001144967.3; = p.L588F on NM_015277.6) | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NLRP7 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 180/428 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRK | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OBSCN | c.12085G>C p.D4029H | Missense Mutation (SNP) | VAF 124/637 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- OR5D3P | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 203/211 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PDZRN4 | c.2276C>T p.S759F (on ENST00000402685 / NM_001164595.2; = p.S501F on NM_013377.4) | Missense Mutation (SNP) | VAF 184/196 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHN1 | c.982G>A p.E328K (on ENST00000379409; = p.E276K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 361/380 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PZP | c.1672A>T p.N558Y | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- QDPR | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- SCN11A | c.178A>G p.R60G | Missense Mutation (SNP) | VAF 197/294 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SKOR1 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 36/1066 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- SLCO1A2 | c.1688C>A p.A563E | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMAD4 | c.1492T>G p.L498V | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF9B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 424/593 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- TENM1 | c.5932C>T p.L1978F | Missense Mutation (SNP) | VAF 463/639 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMEFF2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 132/149 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TOR1AIP2 | c.211_212del p.E71Kfs*4 | Frame Shift Del (DEL) | VAF 102/462 reads (22%) | called by mutect2, pindel, varscan2
- UIMC1 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 99/405 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- VPS35L | c.2529G>A p.V843= | Splice Region (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- VWDE | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 176/430 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- WIZ | c.4021C>T p.P1341S (on ENST00000673675 / NM_001371589.1; = p.P246S on NM_021241.3) | Missense Mutation (SNP) | VAF 254/402 reads (63%) | SIFT tolerated (0.38); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- XIRP1 | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 259/415 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZC3H13 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 273/584 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSWIM5 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 239/251 reads (95%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABCA1 | c.2979C>T p.H993= | Silent (SNP) | VAF 149/301 reads (50%) | called by muse, mutect2, varscan2
- ABCA5 | c.1098T>G p.T366= | Silent (SNP) | VAF 141/143 reads (99%) | catalogued as COSV67017549; called by muse, mutect2, varscan2
- ADAM19 | c.528C>T p.F176= | Silent (SNP) | VAF 194/376 reads (52%) | catalogued as rs199763273, COSV57428271; called by muse, mutect2, varscan2
- ANKRD62 | c.444T>C p.N148= | Silent (SNP) | VAF 60/235 reads (26%) | called by muse, mutect2, varscan2
- ATP11C | c.3177A>C p.V1059= | Silent (SNP) | VAF 86/488 reads (18%) | called by muse, mutect2, varscan2
- CORO2B | c.567C>T p.N189= | Silent (SNP) | VAF 33/617 reads (5%) | called by muse, mutect2
- ERICH3 | c.2031C>G p.T677= | Silent (SNP) | VAF 300/311 reads (96%) | called by muse, mutect2, varscan2
- FREM3 | c.1044C>T p.N348= | Silent (SNP) | VAF 120/478 reads (25%) | catalogued as rs775374923, COSV61682338; called by muse, mutect2
- FRY | c.3402C>T p.F1134= | Silent (SNP) | VAF 172/386 reads (45%) | called by muse, mutect2, varscan2
- GDPGP1 | c.460C>T p.L154= | Silent (SNP) | VAF 261/519 reads (50%) | called by muse, mutect2, varscan2
- GFOD1 | c.1101G>A p.E367= | Silent (SNP) | VAF 454/695 reads (65%) | called by muse, mutect2, varscan2
- GPR101 | c.51G>A p.T17= | Silent (SNP) | VAF 132/852 reads (15%) | called by muse, varscan2
- HELZ2 | c.4407G>A p.P1469= (on ENST00000467148 / NM_001037335.2; = p.P900= on NM_033405.3) | Silent (SNP) | VAF 134/608 reads (22%) | catalogued as rs903203958, COSV101427570; called by muse, varscan2
- IL36RN | c.36G>A p.K12= | Silent (SNP) | VAF 129/141 reads (91%) | called by muse, mutect2, varscan2
- KCNB2 | c.1512C>T p.S504= | Silent (SNP) | VAF 80/370 reads (22%) | catalogued as COSV73052845; called by muse, mutect2, varscan2
- KRTAP13-2 | c.225C>T p.P75= | Silent (SNP) | VAF 110/514 reads (21%) | called by muse, mutect2, varscan2
- MROH2A | c.3999G>A p.L1333= | Silent (SNP) | VAF 119/124 reads (96%) | called by muse, mutect2, varscan2
- NRN1 | c.66G>A p.V22= | Silent (SNP) | VAF 142/478 reads (30%) | called by muse, mutect2, varscan2
- NRXN3 | c.1185C>T p.S395= (on ENST00000335750 / NM_001330195.2; = p.S22= on NM_004796.6) | Silent (SNP) | VAF 253/260 reads (97%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1687C>T p.L563= | Silent (SNP) | VAF 203/513 reads (40%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1866C>T p.I622= | Silent (SNP) | VAF 184/402 reads (46%) | catalogued as rs370339346; called by muse, mutect2, varscan2
- PLPP4 | c.426C>T p.F142= | Silent (SNP) | VAF 281/287 reads (98%) | catalogued as rs754081575; called by muse, mutect2, varscan2
- POLH | c.2121T>C p.F707= | Silent (SNP) | VAF 285/451 reads (63%) | called by muse, mutect2, varscan2
- PPFIA4 | c.228C>T p.L76= | Silent (SNP) | VAF 159/491 reads (32%) | catalogued as rs1159615463, COSV55322708; called by muse, mutect2, varscan2
- PPP1R35 | c.384G>A p.K128= | Silent (SNP) | VAF 294/596 reads (49%) | catalogued as rs1333385479; called by muse, mutect2, varscan2
- RNASEH2A | c.60G>A p.V20= | Silent (SNP) | VAF 34/536 reads (6%) | called by muse, mutect2
- RNF123 | c.3159G>A p.Q1053= | Silent (SNP) | VAF 61/214 reads (29%) | called by muse, mutect2, varscan2
- RPS3A | c.615T>C p.Y205= | Silent (SNP) | VAF 70/256 reads (27%) | catalogued as rs1320534664; called by muse, mutect2, varscan2
- SPATA20 | c.549C>T p.F183= (on ENST00000356488 / NM_001258372.1; = p.F199= on NM_022827.4) | Silent (SNP) | VAF 394/411 reads (96%) | called by muse, mutect2, varscan2
- TAS2R60 | c.360G>A p.V120= | Silent (SNP) | VAF 257/517 reads (50%) | catalogued as COSV60330157; called by muse, mutect2, varscan2
- TEX14 | c.2181G>A p.T727= (on ENST00000240361 / NM_001201457.2; = p.T721= on NM_031272.5) | Silent (SNP) | VAF 403/425 reads (95%) | catalogued as rs769565715; called by muse, mutect2, varscan2
- TGFBR3 | c.1806C>A p.L602= | Silent (SNP) | VAF 116/354 reads (33%) | catalogued as COSV53026875; called by muse, mutect2, varscan2
- VPS35L | c.918C>T p.F306= | Silent (SNP) | VAF 156/349 reads (45%) | catalogued as rs755826217, COSV51991404; called by muse, mutect2, varscan2
- WNT8A | c.834C>T p.N278= | Silent (SNP) | VAF 97/401 reads (24%) | called by muse, mutect2, varscan2
- ATAD3B | c.*340G>A | 3'UTR (SNP) | VAF 391/472 reads (83%) | called by muse, mutect2, varscan2
- OBSCN | c.2653+2059G>C | Intron (SNP) | VAF 53/358 reads (15%) | called by muse, mutect2, varscan2
- PPP2R5C | c.93+2280G>A | Intron (SNP) | VAF 63/241 reads (26%) | called by muse, mutect2, varscan2
